Somatic mutation profile of tumor specimen TCGA-BR-6458-01A (aliquot TCGA-BR-6458-01A-11D-1800-08) from TCGA case TCGA-BR-6458, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 57.7 years (21,069 days).
Specimen TCGA-BR-6458-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b39340c-56e2-4334-8488-51b7e1dfdb5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6458-10A (Blood Derived Normal), aliquot TCGA-BR-6458-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5e30a93-9caa-4036-bb0b-2b3474940fc7

The open-access MAF lists 324 somatic variants for this specimen: 238 protein-altering or splice-affecting, 76 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 76, Frame Shift Del 6, RNA 4, Intron 3, 5'UTR 2, Splice Region 2, Splice Site 2, 3'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.2530A>C p.S844R | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.873); catalogued as COSV55292130; called by muse, mutect2, varscan2
- ABCA8 | c.2550T>G p.S850R | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs1206853333, COSV52203431; called by muse, mutect2, varscan2
- ABI3BP | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1048248155, COSV52539179; called by muse, mutect2, varscan2
- ACAN | c.1646A>C p.K549T | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV61362117; called by muse, mutect2, varscan2
- ACSL6 | c.1340G>A p.R447Q (on ENST00000379240; = p.R472Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs779755365, COSV57299727; called by muse, mutect2, varscan2
- ADAD1 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV56644172; called by muse, mutect2, varscan2
- ADAM10 | c.1426A>G p.S476G | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV53052076; called by muse, mutect2, varscan2
- ADAMTS20 | c.2105A>C p.N702T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67133144, COSV67135569; called by muse, mutect2, varscan2
- ADGRA2 | c.2431T>G p.L811V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV55104154; called by muse, mutect2, varscan2
- ALMS1 | c.12428A>C p.K4143T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.236); catalogued as COSV52511990; called by muse, mutect2, varscan2
- APBB1IP | c.383T>A p.L128* | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as COSV63302824; called by muse, mutect2, varscan2
- APOB | c.911A>G p.K304R | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs1206715687, COSV51939001; called by muse, mutect2, varscan2
- APOD | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58402137; called by muse, mutect2, varscan2
- ATG2B | c.3923G>A p.R1308H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); catalogued as rs773984669, COSV55890781; called by muse, mutect2, varscan2
- AUTS2 | c.386T>G p.L129R | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV61397163, COSV61408520; called by muse, mutect2, varscan2
- CACUL1 | c.626G>T p.R209I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV60994905; called by muse, mutect2
- CALCOCO1 | c.1475A>T p.E492V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50414912; called by muse, mutect2, varscan2
- CALR | c.702+1G>A p.X234_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as COSV57127596; called by muse, mutect2, varscan2
- CATSPER2 | c.1481T>A p.L494H (on ENST00000321596 / NM_001282309.3; = p.L496H on NM_172095.4) | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58661038; called by muse, mutect2, varscan2
- CCDC171 | c.2993C>T p.T998I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs768435593, COSV52643339; called by muse, mutect2, varscan2
- CCDC18 | c.2975T>G p.L992R (on ENST00000343253 / NM_001306076.1; = p.L993R on NM_206886.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV58144336; called by muse, mutect2
- CCDC33 | c.815T>C p.F272S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58352996, COSV58359170; called by mutect2, varscan2
- CCL8 | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV67014020; called by muse, mutect2, varscan2
- CCM2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs942924855, COSV51848931; called by muse, mutect2
- CDH7 | c.569G>C p.R190T | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59887667; called by muse, mutect2, varscan2
- CEP126 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54826362; called by muse, mutect2, varscan2
- CHD8 | c.7001G>A p.R2334Q (on ENST00000646647 / NM_001170629.2; = p.R2055Q on NM_020920.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs373946888; called by muse, mutect2, varscan2
- CKAP5 | c.670A>G p.S224G | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1483685022, COSV56368923; called by muse, mutect2
- CLEC1B | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV53725693; called by muse, mutect2, varscan2
- CNGA3 | c.1577A>C p.K526T | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV55625049; called by muse, mutect2
- COL12A1 | c.5438T>G p.L1813R | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1182620341, COSV100487001, COSV59396415; called by muse, mutect2, varscan2
- COL15A1 | c.3265T>G p.F1089V | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV66645994, COSV66648975; called by muse, mutect2, varscan2
- COL5A1 | c.4580T>G p.I1527S | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.104); catalogued as COSV65670059; called by muse, mutect2, varscan2
- CPNE8 | c.319T>A p.L107I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV58844838; called by muse, mutect2, varscan2
- CPXM2 | c.1463T>C p.L488P | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV53863591; called by muse, mutect2, varscan2
- CRACDL | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV67408547; called by muse, mutect2
- CRB1 | c.3431A>C p.N1144T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.14); catalogued as COSV66331046; called by muse, mutect2, varscan2
- CRYBA4 | c.328T>G p.F110V | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100697867, COSV61322163; called by muse, mutect2, varscan2
- CSMD2 | c.1631A>C p.K544T | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV53920839; called by muse, mutect2, varscan2
- CTNND2 | c.1228T>G p.L410V | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV58861735, COSV58895397; called by muse, mutect2, varscan2
- CYP8B1 | c.1274A>C p.K425T | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV60226647; called by muse, mutect2, varscan2
- DACT1 | c.1497G>C p.E499D | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV60021305, COSV60021753; called by muse, mutect2, varscan2
- DCTN5 | c.524A>C p.K175T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs543504408, COSV55615573; called by muse, mutect2, varscan2
- DDX27 | c.1487A>C p.N496T | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV65608321; called by muse, mutect2, varscan2
- DEUP1 | c.1797A>C p.K599N | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV53212998; called by muse, mutect2, varscan2
- DLC1 | c.4157T>C p.L1386P (on ENST00000276297 / NM_001348081.2; = p.L949P on NM_006094.5) | Missense Mutation (SNP) | VAF 1925/2066 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV104371169, COSV52308744; called by muse, mutect2, varscan2
- DNAH10 | c.12466G>A p.D4156N (on ENST00000409039; = p.D4095N on NM_207437.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267751841, COSV68995271; called by muse, varscan2
- DNAH11 | c.1010T>G p.L337R | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV60960178; called by muse, mutect2, varscan2
- DNAH11 | c.2366T>G p.L789R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60960189; called by muse, mutect2
- DNAH2 | c.5971C>T p.R1991C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs762353376, COSV66720727; called by muse, mutect2, varscan2
- DNAH5 | c.11783A>C p.K3928T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV54231387; called by muse, mutect2
- DNAH5 | c.11034A>C p.K3678N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV54231396; called by muse, mutect2
- DYTN | c.1601T>C p.L534P | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101510870, COSV71752270; called by muse, mutect2, varscan2
- EFCAB5 | c.3766C>T p.R1256C | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190450097, COSV57926515; called by muse, mutect2, varscan2
- EFCAB6 | c.1979A>C p.K660T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV53065139; called by muse, mutect2, varscan2
- EGLN2 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58280289; called by muse, mutect2, varscan2
- EIF4E | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV55187624; called by muse, mutect2, varscan2
- EXOSC4 | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV60155920; called by muse, mutect2
- FAM133A | c.93A>C p.Q31H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.937); catalogued as COSV59075987; called by muse, mutect2, varscan2
- FAM13A | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1215286484, COSV52004413; called by muse, mutect2, varscan2
- FAT4 | c.12068A>T p.D4023V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV58689940, COSV58698578; called by muse, mutect2, varscan2
- FAT4 | c.13412T>A p.L4471H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV58689957, COSV58703090; called by muse, mutect2, varscan2
- FBLN2 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs775113995, COSV55485680; called by muse, mutect2, varscan2
- FBXO30 | c.1922A>T p.K641M | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV52791489; called by muse, mutect2, varscan2
- FCRL6 | c.566T>G p.V189G | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58941468; called by muse, mutect2, varscan2
- FGD6 | c.2495C>G p.S832C | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59693890, COSV59696758; called by muse, mutect2, varscan2
- FZD3 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1374167678, COSV53535951; called by muse, varscan2
- FZD3 | c.1368A>C p.E456D | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV53535959; called by muse, varscan2
- FZD8 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65967972; called by muse, mutect2, varscan2
- G0S2 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs775447110, COSV65433170; called by muse, mutect2, varscan2
- GABRR3 | c.1225A>G p.R409G | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV72115915; called by muse, mutect2, varscan2
- GALNT17 | c.878A>G p.H293R | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs1201589476, COSV61166618; called by muse, mutect2
- GALNT17 | c.961A>G p.R321G | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61166624; called by muse, mutect2
- GBP4 | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV63254650; called by muse, mutect2, varscan2
- GFRA1 | c.811T>C p.S271P | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV62606938; called by muse, mutect2, varscan2
- GFRA2 | c.907T>G p.F303V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.473); catalogued as COSV60779529; called by muse, mutect2
- GJA9 | c.673T>G p.L225V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62532258; called by muse, mutect2
- GNB4 | c.376T>A p.L126I | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV51709877; called by muse, mutect2, varscan2
- GPC5 | c.1314A>C p.K438N | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV65604082; called by muse, mutect2, varscan2
- GPRC5B | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.995); catalogued as COSV56026997, COSV56029018; called by muse, mutect2, varscan2
- GPRC6A | c.315A>C p.E105D | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV59953590; called by muse, mutect2, varscan2
- GRIA1 | c.2030A>C p.K677T | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as COSV53607168; called by muse, mutect2, varscan2
- GRIN3A | c.2498A>G p.K833R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.427); catalogued as COSV62454790; called by muse, mutect2, varscan2
- GRK3 | c.1525T>G p.F509V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60796876; called by muse, mutect2, varscan2
- GRM5 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV59609111, COSV59634159; called by muse, mutect2, varscan2
- GUCY1A2 | c.1623A>C p.Q541H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56482090, COSV56489584; called by muse, mutect2, varscan2
- GUCY2F | c.1618A>C p.S540R | Missense Mutation (SNP) | VAF 71/330 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV54303666; called by muse, mutect2, varscan2
- HGD | c.1097G>T p.S366I | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52198864; called by muse, mutect2, varscan2
- HMGCLL1 | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51442476, COSV51451307; called by muse, mutect2, varscan2
- HOXA11 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50053338; called by muse, mutect2
- HSPB3 | c.426A>C p.E142D | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV57357123; called by muse, mutect2, varscan2
- HTRA1 | c.1301T>C p.I434T | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64564418; called by muse, mutect2, varscan2
- IFIT3 | c.345T>G p.I115M | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as COSV51079301; called by muse, mutect2, varscan2
- IKZF4 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56268960; called by muse, mutect2, varscan2
- IL11 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV52772825; called by muse, mutect2, varscan2
- IL18R1 | c.534A>C p.E178D | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as rs1234781890, COSV99295066; called by muse, mutect2, varscan2
- IL1RAP | c.1381A>C p.S461R | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50763153; called by muse, mutect2, varscan2
- INVS | c.775C>A p.L259M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52443429; called by muse, mutect2, varscan2
- ITGAV | c.1649G>A p.S550N | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.054); catalogued as COSV53713836; called by muse, mutect2, varscan2
- ITIH5 | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV53667954; called by muse, mutect2, varscan2
- ITK | c.516A>C p.E172D | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV70062893; called by muse, mutect2, varscan2
- ITSN2 | c.1940T>G p.L647R | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV61948622; called by muse, mutect2, varscan2
- JHY | c.2216A>C p.N739T | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV57076090; called by muse, mutect2, varscan2
- KCNH7 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.455); catalogued as rs1399121980, COSV59799648; called by muse, mutect2, varscan2
- KCNK10 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56646455; called by muse, mutect2, varscan2
- KCTD16 | c.1274A>C p.K425T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs753026633, COSV72579254; called by muse, mutect2, varscan2
- KMT2B | c.4198C>T p.R1400C | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs747829749, COSV55862810; called by muse, mutect2, varscan2
- LILRA4 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52492629; called by muse, mutect2, varscan2
- LIMA1 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV57966047; called by muse, mutect2, varscan2
- LPL | c.776-2A>G p.X259_splice | Splice Site (SNP) | VAF 40/183 reads (22%) | catalogued as COSV60931468; called by muse, mutect2, varscan2
- LUZP2 | c.621A>C p.K207N | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1302260315, COSV61207407; called by muse, mutect2, varscan2
- MADCAM1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs201782118; called by muse, varscan2
- MAP3K21 | c.1876A>C p.K626Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV64041941; called by muse, mutect2, varscan2
- MARCHF8 | c.548A>G p.E183G | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60572839; called by muse, mutect2, varscan2
- MC4R | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as COSV55352307; called by muse, mutect2
- MEPE | c.356A>C p.K119T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV63073098; called by muse, mutect2, varscan2
- MFSD6 | c.635T>G p.V212G | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV55623168; called by muse, mutect2
- MIA3 | c.252A>T p.E84D | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV60513954; called by muse, mutect2, varscan2
- MUC16 | c.28456A>C p.T9486P | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV67472481; called by muse, mutect2, varscan2
- MYH2 | c.4556C>T p.T1519M | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs138796340, COSV55443052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.5404T>G p.L1802V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.388); catalogued as COSV62751651; called by muse, mutect2, varscan2
- MYPN | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as rs771703762, COSV62734799; called by muse, mutect2, varscan2
- N4BP2 | c.1640A>C p.K547T | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54702882; called by muse, mutect2, varscan2
- NAA25 | c.2768T>C p.L923P | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV55704993; called by muse, mutect2, varscan2
- NAV3 | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs770984486, COSV57085751; called by muse, mutect2, varscan2
- NAV3 | c.5492T>G p.I1831S (on ENST00000397909 / NM_001024383.2; = p.I1809S on NM_014903.6) | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57085765; called by muse, mutect2, varscan2
- NDST3 | c.2354A>C p.K785T | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as COSV56613634; called by muse, mutect2, varscan2
- NEB | c.10712A>T p.K3571M | Missense Mutation (SNP) | VAF 78/330 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV51424243, COSV51455686; called by muse, mutect2, varscan2
- NOX5 | c.909A>C p.Q303H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV52990033, COSV99535032; called by muse, mutect2, varscan2
- NRP1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771071490, COSV55169067; called by muse, mutect2, varscan2
- NT5C1B | c.965A>G p.D322G (on ENST00000359846 / NM_001199086.2; = p.D262G on NM_033253.4) | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV58396438; called by muse, mutect2, varscan2
- NXPE1 | c.775A>C p.T259P (on ENST00000424269; = p.T117P on NM_152315.5) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.251); catalogued as COSV52630114; called by muse, mutect2, varscan2
- OR1N2 | c.43T>C p.F15L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV65460794; called by muse, mutect2, varscan2
- OR2A12 | c.245C>A p.A82E | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs1227848321, COSV68821588; called by muse, mutect2, varscan2
- OR2B11 | c.503T>A p.V168E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV59510453; called by muse, mutect2
- OR2C1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs780012660, COSV59240468; called by muse, mutect2, varscan2
- OR2T6 | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1266238746, COSV63216501; called by muse, mutect2, varscan2
- OR51A7 | c.75T>G p.I25M | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as COSV63788496, COSV63788793; called by muse, mutect2, varscan2
- OR5AC2 | c.134T>G p.L45R | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62279641; called by muse, mutect2, varscan2
- OR5B2 | c.899A>G p.K300R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV56907885; called by muse, mutect2, varscan2
- OR5K2 | c.145A>C p.I49L | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV71143250; called by muse, mutect2, varscan2
- OR5L1 | c.553T>G p.L185V | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.902); catalogued as COSV61732703; called by muse, mutect2, varscan2
- OR7A17 | c.311T>A p.F104Y | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.055); catalogued as COSV100541660, COSV59413849, COSV59414424; called by muse, mutect2, varscan2
- OR8H1 | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV57294332, COSV57294450; called by muse, mutect2, varscan2
- OSBPL8 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.053); catalogued as COSV53883972; called by muse, mutect2, varscan2
- OSR2 | c.524A>C p.K175T | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV52557195, COSV52557359; called by muse, mutect2, varscan2
- OTOGL | c.6100T>A p.C2034S (on ENST00000547103; = p.C2025S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100087209; called by muse, mutect2, varscan2
- OXR1 | c.1237A>C p.T413P (on ENST00000442977 / NM_001198532.1; = p.T412P on NM_018002.3) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.248); catalogued as COSV56330442; called by muse, mutect2, varscan2
- PAGE3 | c.139A>C p.S47R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.351); catalogued as COSV100891984; called by muse, mutect2, varscan2
- PASD1 | c.1433A>C p.N478T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV64855731; called by muse, varscan2
- PBX2 | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66708995; called by muse, mutect2, varscan2
- PCDH19 | c.1356C>A p.H452Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as COSV55264843; called by muse, mutect2, varscan2
- PCDHA6 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs188962276, COSV65342455; called by muse, mutect2, varscan2
- PCDHB12 | c.1276T>A p.L426M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.305); catalogued as COSV53395988, COSV53397545; called by muse, mutect2, varscan2
- PCDHGB2 | c.2201A>C p.K734T | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.616); catalogued as COSV53964675; called by muse, mutect2, varscan2
- PCLO | c.11631A>C p.Q3877H | Missense Mutation (SNP) | VAF 94/1631 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61640524; called by muse, mutect2
- PCOLCE2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs376768304; called by muse, mutect2, varscan2
- PKHD1 | c.9763T>C p.W3255R | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.092); catalogued as COSV61880203; called by muse, mutect2, varscan2
- PLEC | c.12595C>A p.P4199T (on ENST00000322810 / NM_201380.4; = p.P4089T on NM_000445.5) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59646774; called by muse, mutect2, varscan2
- PLXNA1 | c.3660G>A p.T1220= | Splice Region (SNP) | VAF 13/40 reads (33%) | catalogued as rs745908091, COSV52527604; called by muse, mutect2, varscan2
- POGLUT1 | c.738A>C p.K246N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.717); catalogued as COSV55157055; called by muse, mutect2, varscan2
- PPFIA2 | c.2567A>C p.E856A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV61036154; called by muse, mutect2, varscan2
- PPFIA4 | c.3544G>A p.A1182T (on ENST00000447715; = p.A1183T on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); catalogued as COSV55316381; called by muse, mutect2, varscan2
- PREX2 | c.2651A>C p.K884T | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV55751124; called by muse, mutect2
- PRKAR2B | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55925490; called by muse, mutect2, varscan2
- PRKD2 | c.1963A>G p.I655V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV52187386; called by muse, mutect2
- PRKD3 | c.2238A>C p.E746D | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52214259; called by muse, mutect2, varscan2
- PRKG1 | c.596T>G p.L199R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV64795233; called by muse, mutect2, varscan2
- PRPH2 | c.20A>C p.K7T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV57837532; called by muse, mutect2, varscan2
- PRSS23 | c.1007T>G p.I336S | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV54707036; called by muse, mutect2, varscan2
- PSG2 | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV100283561, COSV61545508; called by muse, mutect2, varscan2
- PXDNL | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1390725251, COSV62485704; called by muse, mutect2
- RASGRF2 | c.1578C>A p.D526E | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54131616; called by muse, mutect2
- RASGRP1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs766659143, COSV60365613; called by muse, mutect2
- RBM5 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV61737795; called by muse, mutect2, varscan2
- RGS17 | c.457T>A p.S153T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV52808593; called by muse, mutect2, varscan2
- RHOBTB1 | c.2060G>A p.C687Y | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs1285133329, COSV61958917; called by muse, mutect2
- RNF17 | c.2238A>C p.K746N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV55042045; called by muse, mutect2, varscan2
- SEMA6D | c.1947A>C p.E649D (on ENST00000316364 / NM_153618.2; = p.E587D on NM_020858.2) | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV60371874, COSV60373482, COSV60380284; called by muse, mutect2, varscan2
- SEZ6L2 | c.1246G>A p.V416M (on ENST00000308713 / NM_001114099.3; = p.V346M on NM_012410.4) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs775884420, COSV58100305; called by muse, mutect2, varscan2
- SH3TC2 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60464254; called by muse, mutect2, varscan2
- SLC12A5 | c.3250G>A p.V1084M (on ENST00000454036 / NM_001134771.2; = p.V1061M on NM_020708.5) | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV51646856; called by muse, mutect2
- SLC35F1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs138680595, COSV64500406; called by muse, mutect2, varscan2
- SLC39A6 | c.429A>C p.K143N | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.69); catalogued as COSV52369669; called by muse, mutect2, varscan2
- SLIT3 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60613606; called by muse, mutect2, varscan2
- SNAPC4 | c.2888C>G p.P963R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV53734080; called by muse, mutect2, varscan2
- SNED1 | c.430T>G p.F144V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60025610; called by muse, mutect2, varscan2
- SPART | c.1442A>C p.K481T | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100768731, COSV100768927, COSV62085820; called by muse, mutect2, varscan2
- SPEF2 | c.2957A>G p.K986R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV61549063; called by muse, mutect2, varscan2
- STAG3 | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs781730286, COSV57931314; called by muse, mutect2, varscan2
- SYCP2 | c.3539C>T p.P1180L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV100698218; called by muse, mutect2, varscan2
- TAS2R16 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV50797307; called by muse, mutect2, varscan2
- TBXT | c.1198C>A p.L400M | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV51618530, COSV99752949; called by muse, mutect2, varscan2
- TEAD4 | c.890A>C p.K297T | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63281408; called by muse, mutect2, varscan2
- TESPA1 | c.1067C>T p.S356F (on ENST00000316577 / NM_001098815.3; = p.S218F on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV57259402; called by muse, mutect2, varscan2
- TFB2M | c.934T>A p.L312I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63624986; called by muse, mutect2, varscan2
- TG | c.5046A>C p.Q1682H | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV55079940; called by muse, mutect2, varscan2
- TGFB2 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 136/445 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV65109598; called by muse, mutect2, varscan2
- TIAM1 | c.2687T>C p.L896P | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54555681; called by muse, mutect2
- TLR6 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1259319221, COSV67935346; called by muse, mutect2, varscan2
- TMEM225 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.15); catalogued as COSV66693470; called by muse, mutect2, varscan2
- TMEM237 | c.1203G>C p.E401D (on ENST00000409883 / NM_001044385.3; = p.E393D on NM_152388.4) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53805173; called by muse, mutect2, varscan2
- TOPBP1 | c.25T>G p.F9V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV53436897; called by muse, mutect2, varscan2
- TRHDE | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs1219010746, COSV53836177; called by muse, mutect2, varscan2
- TRIM32 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV57785628; called by muse, mutect2, varscan2
- TRPC5 | c.649A>C p.I217L | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.525); catalogued as COSV53292951; called by muse, mutect2, varscan2
- TRPM3 | c.3177A>C p.E1059D (on ENST00000357533 / NM_001366142.2; = p.E902D on NM_020952.6) | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62587704; called by muse, mutect2, varscan2
- TSC2 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142919353; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TSHZ3 | c.965A>T p.K322M | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53673909; called by muse, mutect2
- TTC17 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV50009781, COSV50011520; called by muse, mutect2, varscan2
- TTC6 | c.1532T>G p.L511R (on ENST00000267368; = p.L1877R on NM_001310135.3) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99941829; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | catalogued as rs768996038, COSV57882295; called by mutect2, pindel, varscan2
- UGT2A1 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54142469; called by muse, mutect2, varscan2
- USP28 | c.1135C>G p.P379A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50165856; called by muse, mutect2, varscan2
- USP49 | c.1876+5G>A | Splice Region (SNP) | VAF 32/170 reads (19%) | catalogued as COSV51897937; called by muse, mutect2, varscan2
- UTRN | c.1802T>G p.L601R | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV62337683; called by muse, mutect2, varscan2
- UTRN | c.3451C>T p.R1151W | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs375499592; called by muse, mutect2, varscan2
- UTRN | c.4923A>C p.E1641D | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV62337696; called by muse, mutect2, varscan2
- VPS16 | c.1987A>C p.N663H | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66795769; called by muse, mutect2, varscan2
- VPS35L | c.676T>G p.F226V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51984702; called by muse, mutect2, varscan2
- WNT5A | c.848A>G p.K283R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.083); catalogued as rs1256476123, COSV52837689; called by muse, mutect2, varscan2
- ZBTB16 | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV60094242; called by muse, mutect2, varscan2
- ZEB1 | c.1550A>C p.E517A | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV58046238; called by muse, mutect2, varscan2
- ZNF285 | c.924A>C p.K308N | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV58409394; called by muse, mutect2, varscan2
- ZNF317 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56110066; called by muse, mutect2, varscan2
- ZNF404 | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs755492408, COSV60987647; called by muse, mutect2, varscan2
- ZNF43 | c.531A>T p.K177N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV100731996, COSV61684292; called by muse, mutect2, varscan2
- ZNF613 | c.1309T>G p.F437V (on ENST00000293471 / NM_001031721.4; = p.F401V on NM_024840.4) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53272368; called by mutect2, varscan2
- ZNF648 | c.1673A>G p.K558R | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs910622410, COSV60571385; called by muse, mutect2, varscan2
- ZSCAN25 | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV53553279; called by muse, mutect2, varscan2
- IGHV7-81 | c.25T>G p.F9V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- KIF24 | c.2686del p.R896Gfs*4 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.189A>C p.E63D | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MIS18BP1 | c.766_767del p.S256Yfs*6 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | called by pindel, varscan2
- MRPL49 | c.315del p.Q106Rfs*2 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by mutect2, pindel, varscan2
- PRKCH | c.217dup p.C73Lfs*3 | Frame Shift Ins (INS) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- SPTA1 | c.3499del p.S1167Lfs*73 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- TMF1 | c.814_827del p.S272Tfs*27 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel
- ADAMTS17 | c.1974C>T p.C658= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs750942602, COSV51483189; called by muse, mutect2, varscan2
- AFF3 | c.2481C>T p.D827= | Silent (SNP) | VAF 25/292 reads (9%) | catalogued as rs911084760, COSV57857007; called by muse, mutect2
- ALG10B | c.981G>A p.L327= | Silent (SNP) | VAF 34/214 reads (16%) | catalogued as COSV58143516; called by muse, mutect2, varscan2
- ARFGAP1 | c.606C>T p.N202= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs775007952, COSV62263253; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1476C>T p.A492= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV52269907; called by muse, mutect2, varscan2
- ATP8A1 | c.780A>T p.T260= | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as COSV52537321; called by muse, mutect2, varscan2
- BMP5 | c.726T>G p.A242= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as COSV63703935; called by muse, mutect2, varscan2
- BRIX1 | c.24G>A p.R8= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV57715293; called by muse, mutect2, varscan2
- CNTNAP2 | c.1632C>T p.F544= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as rs778731812, COSV62144222; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL24A1 | c.1257C>T p.N419= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs760139603, COSV65305283; called by muse, mutect2, varscan2
- COL6A3 | c.3405G>C p.L1135= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV55093185; called by muse, mutect2, varscan2
- COLEC11 | c.636C>T p.G212= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs141570591; called by muse, mutect2, varscan2
- DTX4 | c.1407C>T p.T469= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV57091662; called by muse, mutect2, varscan2
- EPC1 | c.2046C>T p.I682= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs763223458, COSV53926516; called by muse, mutect2, varscan2
- FAM47A | c.1860T>C p.A620= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV60497522; called by muse, mutect2, varscan2
- FRMD8 | c.1302G>C p.P434= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2
- FSHR | c.1071A>G p.E357= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV58625488; called by muse, mutect2, varscan2
- GABARAPL2 | c.177G>A p.Q59= | Silent (SNP) | VAF 37/192 reads (19%) | catalogued as COSV50673425; called by muse, mutect2, varscan2
- GRIA2 | c.1002A>G p.P334= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV52393268; called by muse, mutect2, varscan2
- HAO1 | c.108T>C p.T36= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV66492320; called by muse, mutect2, varscan2
- HOXA11 | c.90C>T p.L30= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as COSV50053348; called by muse, mutect2
- HOXD10 | c.1020T>G p.S340= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV50892298; called by mutect2, varscan2
- IL36RN | c.378A>G p.E126= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV61010610; called by muse, mutect2, varscan2
- KCNG1 | c.1125C>T p.R375= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1270664807, COSV65369365; called by muse, mutect2, varscan2
- KCNH5 | c.1296C>T p.T432= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1177748365, COSV100526794, COSV59762950; called by muse, mutect2, varscan2
- KLRF1 | c.555T>G p.T185= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV54381069; called by muse, mutect2, varscan2
- LAMB4 | c.1683C>A p.L561= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV52721409; called by muse, mutect2, varscan2
- LGI2 | c.237A>C p.R79= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV66123169; called by muse, mutect2, varscan2
- MAGEB4 | c.589A>C p.R197= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV66775890; called by muse, mutect2, varscan2
- MAST1 | c.1182C>T p.R394= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs778656447, COSV52248363; called by muse, mutect2, varscan2
- MICU3 | c.504T>C p.F168= | Silent (SNP) | VAF 43/391 reads (11%) | catalogued as COSV58846611; called by muse, mutect2, varscan2
- MNDA | c.610A>C p.R204= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV63741058; called by muse, mutect2
- MTCL1 | c.1773G>A p.E591= (on ENST00000306329 / NM_001378206.1; = p.E231= on NM_015210.4) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV60407079; called by muse, mutect2, varscan2
- MUC4 | c.13467C>T p.S4489= (on ENST00000463781 / NM_018406.7; = p.S253= on NM_004532.6) | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs373895108; called by muse, mutect2, varscan2
- NES | c.3267C>G p.A1089= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV63961352; called by muse, mutect2, varscan2
- NINL | c.1929C>T p.Y643= | Silent (SNP) | VAF 21/174 reads (12%) | catalogued as rs148406486, COSV54003744; called by muse, mutect2, varscan2
- NPAS1 | c.849T>C p.L283= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV71384080; called by muse, mutect2, varscan2
- NYAP2 | c.561C>T p.S187= | Silent (SNP) | VAF 10/218 reads (5%) | catalogued as COSV56007508; called by muse, mutect2
- OBSCN | c.5676C>T p.T1892= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs763832348, COSV52783388, COSV99477225; called by muse, mutect2, varscan2
- OR4A5 | c.282T>G p.G94= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV60521509; called by muse, mutect2, varscan2
- OR5T1 | c.354T>G p.T118= | Silent (SNP) | VAF 32/191 reads (17%) | catalogued as COSV57302613, COSV57303079; called by muse, mutect2, varscan2
- PCDHA8 | c.1407G>A p.P469= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs782204148, COSV65337873; called by muse, mutect2, varscan2
- PCLO | c.11754A>G p.Q3918= | Silent (SNP) | VAF 86/1332 reads (6%) | catalogued as COSV61615390, COSV61633767, COSV61640511; called by muse, mutect2
- PGA5 | c.786C>T p.N262= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as rs139579497; called by muse, mutect2, varscan2
- PHOSPHO2 | c.114T>G p.S38= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs1164230197, COSV55867593; called by muse, mutect2, varscan2
- PLEC | c.6855G>A p.R2285= (on ENST00000322810 / NM_201380.4; = p.R2175= on NM_000445.5) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV59646810, COSV59671077; called by muse, mutect2, varscan2
- PXDN | c.3819C>A p.I1273= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV53236829, COSV53246677; called by muse, mutect2, varscan2
- RALGPS1 | c.1674A>G p.*558= | Silent (SNP) | VAF 41/261 reads (16%) | catalogued as COSV52224092; called by muse, mutect2, varscan2
- RELN | c.1507A>C p.R503= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV59008251; called by muse, mutect2, varscan2
- REV3L | c.6825T>G p.T2275= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100725146; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- ROBO4 | c.249G>T p.L83= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs746420072, COSV60624900; called by muse, mutect2, varscan2
- RPL10 | c.501C>T p.I167= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV50010450; called by muse, mutect2, varscan2
- RUNX2 | c.1485C>T p.D495= (on ENST00000371438; = p.D473= on NM_001015051.3) | Silent (SNP) | VAF 31/164 reads (19%) | catalogued as rs377403216; called by muse, mutect2, varscan2
- SACS | c.9495T>G p.T3165= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV66541261; called by muse, mutect2, varscan2
- SALL4 | c.2151G>A p.S717= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs1286697279, COSV53853052; called by muse, mutect2, varscan2
- SCYL2 | c.186A>C p.A62= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV62569208; called by muse, mutect2
- SIRT1 | c.1752T>G p.T584= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV53018722; called by muse, mutect2
- SLC29A3 | c.15A>C p.S5= | Silent (SNP) | VAF 22/308 reads (7%) | catalogued as COSV64385335; called by muse, mutect2
- SLC35F4 | c.177A>C p.T59= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1452463272, COSV60265230; called by muse, mutect2, varscan2
- SLCO4C1 | c.261T>G p.S87= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV60516680; called by muse, mutect2, varscan2
- SNTB1 | c.208A>C p.R70= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1261192367, COSV67326968; called by muse, mutect2
- SOCS7 | c.936G>T p.L312= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1396959670; called by muse, mutect2
- SOGA3 | c.1452A>G p.Q484= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs556620844, COSV64106983; called by muse, mutect2
- SORBS3 | c.1569C>T p.D523= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs146729720, COSV53553235; called by muse, mutect2, varscan2
- SPEF2 | c.5434A>C p.R1812= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs768580531, COSV57429729; called by muse, mutect2, varscan2
- STPG2 | c.723T>A p.G241= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as COSV54802303; called by muse, mutect2, varscan2
- SVIL | c.2541C>T p.N847= (on ENST00000355867 / NM_021738.3; = p.N421= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as rs746176867, COSV63444214; called by muse, mutect2, varscan2
- SYNE1 | c.18654A>G p.Q6218= (on ENST00000367255 / NM_182961.4; = p.Q6147= on NM_033071.3) | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV55005811; called by muse, mutect2, varscan2
- SYNGR1 | c.423C>T p.N141= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs774800353, COSV53368530; called by muse, mutect2, varscan2
- TBC1D5 | c.1488T>C p.P496= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV53759828; called by muse, mutect2, varscan2
- TG | c.5262A>C p.S1754= | Silent (SNP) | VAF 23/232 reads (10%) | catalogued as COSV55079954; called by muse, mutect2, varscan2
- TMEM19 | c.136T>C p.L46= | Silent (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2
- WHAMM | c.2091A>G p.P697= | Silent (SNP) | VAF 43/284 reads (15%) | catalogued as COSV54497057; called by muse, mutect2, varscan2
- ZFPM2 | c.1506T>G p.S502= | Silent (SNP) | VAF 40/259 reads (15%) | catalogued as COSV65874107; called by muse, mutect2, varscan2
- ZNF99 | c.180A>G p.K60= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1230944543, COSV68055940; called by muse, mutect2, varscan2
- ABCB5 | c.1707+411T>C | Intron (SNP) | VAF 29/269 reads (11%) | catalogued as COSV99328282; called by muse, mutect2, varscan2
- AGAP7P | n.1278C>T | RNA (SNP) | VAF 50/230 reads (22%) | catalogued as rs782278610; called by muse, mutect2, varscan2
- ATP2B4 | c.3309+5658G>A | Intron (SNP) | VAF 13/87 reads (15%) | catalogued as rs141349663; called by muse, mutect2, varscan2
- DCHS2 | n.551G>A | RNA (SNP) | VAF 13/54 reads (24%) | catalogued as rs765510888, COSV59728852; called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.24T>C | RNA (SNP) | VAF 31/211 reads (15%) | catalogued as rs1563393863; called by muse, mutect2, varscan2
- IL19 | c.-91G>A | 5'UTR (SNP) | VAF 15/106 reads (14%) | catalogued as rs764102395, COSV61592991; called by muse, mutect2, varscan2
- LRAT | c.*2T>G | 3'UTR (SNP) | VAF 29/168 reads (17%) | catalogued as COSV100312102; called by muse, mutect2, varscan2
- NBPF7 | n.1009A>C | RNA (SNP) | VAF 21/247 reads (9%) | called by muse, mutect2
- OBSCN | c.4585+2802A>T | Intron (SNP) | VAF 6/144 reads (4%) | catalogued as COSV99477068, COSV99482951; called by muse, mutect2
- TPST1 | c.-2A>C | 5'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100507054; called by muse, mutect2
